Gene-level copy-number profile of tumor specimen TCGA-HU-A4HD-01A from TCGA case TCGA-HU-A4HD, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 73.1 years (26,699 days).
Specimen TCGA-HU-A4HD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.6eb0ad58-e520-4ac4-b1f3-c52a9277a3ff.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HU-A4HD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e66bf3c7-d817-4742-80aa-4efd4421dfb1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 2,532; copy number 2: 31,118; copy number 3: 16,603; copy number 4: 5,924; copy number 5: 1,337; copy number 6: 591; copy number 7: 1,253; copy number 8: 248; copy number 9: 43; copy number 11: 9; copy number 12: 117; copy number 29: 1; copy number 30: 1; copy number 32: 21.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HU-A4HD-01A-11D-A253-01): tumor purity 0.53, ploidy 2.73, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:212,581,357–213,284,205, 12 genes: AC093865.1, LINC01878, PCED1CP, AC108066.1, MIR4776-1, MIR4776-2, AC108066.2, IKZF2, AC079610.1, LINC01953, AC079610.2, SPAG16-DT.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,621 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:20,032,650–20,246,387, 9 genes, copy number 11: LAPTM4A, LAPTM4A-DT, AC098828.1, RPS16P2, RN7SL140P, RNU6-961P, SDC1, DRG1P1, RNU7-113P.
- chr3:88,149,959–94,131,832, 27 genes, copy number 5: C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19, ABBA01000933.1, ABBA01000935.2, RNU6-488P, PROS1, Y_RNA, RNU6-511P, ARL13B, HMGN1P7, STX19, DHFR2, NSUN3, RBBP4P2.
- chr5:142,036,707–142,168,387, 3 genes, copy number 5: AC005740.2, NDFIP1, AC091825.3.
- chr7:42,661,716–55,595,006, 213 genes, copy number 5–6 (broad region; genes not listed).
- chr8:56,300,010–145,066,685, 1,375 genes, copy number 6–7 (broad region; genes not listed).
- chr11:74,397,549–74,669,117, 11 genes, copy number 8: AP001372.1, AP001085.1, MIR548AL, KCNE3, AP001372.3, CYCSP27, AP001372.4, LIPT2, AP001372.2, POLD3, RANP3.
- chr11:109,741,625–110,296,712, 8 genes, copy number 6 (within-gene range 3–6): LINC02715, RDX, TFAMP2, AP001981.2, RPSAP50, AP001981.1, AP001889.1, ZC3H12C.
- chr11:117,199,370–117,877,486, 19 genes, copy number 5: TAGLN, PCSK7, AP000892.4, RNF214, AP000892.2, BACE1, BACE1-AS, AP000892.3, CEP164, AP000892.1, PRR13P3, DSCAML1, AP000711.1, AP001554.1, FXYD2, AP000757.2, FXYD6-FXYD2, AP000757.1, FXYD6.
- chr12:24,993,424–25,885,855, 24 genes, copy number 5: C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, MIR4302, AC019209.1.
- chr13:36,168,217–36,490,441, 8 genes, copy number 5: SOHLH2, CCDC169-SOHLH2, CCDC169, RNU6-71P, SPART, SPART-AS1, CCNA1, H2ACP1.
- chr13:36,949,738–42,814,897, 96 genes, copy number 5–12 (within-gene range 3–12) (broad region; genes not listed).
- chr13:69,221,866–92,873,682, 233 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr17:39,566,915–39,977,768, 21 genes, copy number 32 (within-gene range 3–32): AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA.
- chr17:64,147,227–64,308,690, 2 genes, copy number 29–30 (within-gene range 3–30): TEX2, RPL31P57.
- chr18:47,390–24,986,980, 467 genes, copy number 6–12 (within-gene range 3–12) (broad region; genes not listed).
- chr18:30,780,006–31,478,702, 14 genes, copy number 6: AC090506.2, AC016382.1, RNU6-857P, DSC3, DSC2, DSCAS, DSC1, AC012417.1, DSG1, DSG1-AS1, RNU6-167P, DSG4, Y_RNA, DSG3.
- chr19:29,665,459–30,228,715, 16 genes, copy number 5–12: PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1.
- chr19:32,102,088–32,485,895, 7 genes, copy number 7: LINC01782, AC011518.1, AC074139.1, RNA5SP472, ZNF507, AC007773.1, DPY19L3.
- chr19:32,655,016–33,130,542, 18 genes, copy number 5 (within-gene range 2–5): RN7SL789P, AC008474.1, RGS9BP, AC008736.1, NUDT19, AC008736.2, TDRD12, AC008805.1, SLC7A9, AC008805.2, RN7SKP22, CEP89, RPL31P60, FAAP24, RHPN2, AC008521.1, AC008521.2, GPATCH1.
- chr19:36,797,502–37,730,733, 40 genes, copy number 5: ZNF790-AS1, ZNF790, ZNF345, Y_RNA, ZNF829, RPL31P61, ZNF568, ZNF420, AC010632.3, AC010632.1, AC010632.2, AC012309.1, ZNF585A, AC012309.2, ZNF585B, ZNF383, AC016590.1, LINC01535, AC016590.4, ZNF875, AC016590.3, AC016590.2, ZNF527, AC008806.1, ZNF569, ZNF570, ZNF793-AS1, AC022148.2, ZNF793, AC022148.1, ZNF571-AS1, ZNF540, ZNF571, ZFP30, ZNF781, AC093227.2, SELENOKP1, ZNF607, AC093227.1, AC093227.3.
- chr19:46,039,748–46,471,563, 24 genes, copy number 6: IGFL4, AC007785.1, AC007785.2, IGFL3, TGIF1P1, IGFL2, AC006262.2, IGFL2-AS1, IGFL1P1, AC006262.1, RPL12P41, AC006262.3, IGFL1, AC006262.4, IGFL1P2, HIF3A, RNU6-924P, AC007193.2, PPP5C, AC007193.1, AC007193.3, CCDC8, PNMA8C, PNMA8A.
- chr19:46,486,906–46,496,502, 2 genes, copy number 6: PNMA8B, AC011484.1.
- chr19:56,087,366–56,799,602, 43 genes, copy number 9 (within-gene range 2–9): ZNF787, Y_RNA, AC024580.2, ZNF444, AC024580.1, GALP, ZSCAN5B, ZSCAN5C, AC011506.1, ZSCAN5A, ZSCAN5DP, EDDM13, AC006116.5, AC006116.7, Y_RNA, VN2R17P, AC006116.1, AC006116.3, AC006116.2, AC006116.6, AC006116.8, ZNF542P, ZNF582, AC006116.9, SLC25A36P1, AC006116.4, ZNF582-AS1, ZNF583, ZNF667, ZNF667-AS1, AC004696.2, AC004696.1, ZNF471, AC005498.1, AC005498.2, ZFP28, AC005498.3, ZNF470, SIGLEC31P, ZNF71, ZIM2-AS1, SMIM17, ZNF835.
- chr19:57,411,161–58,605,223, 107 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr20:87,250–17,968,980, 330 genes, copy number 5–8 (broad region; genes not listed).
- chr20:17,962,710–17,991,122, 2 genes, copy number 8: SNORD17, MGME1.
- chr20:37,602,852–60,083,872, 502 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,545. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
